ALCHEMIST case ALCH-B204 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/ba50c7c7-f2ac-434d-8230-bf6dd975b272

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 56.3 years (20,571 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B204-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B204-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B204-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 22; Percent tumor nuclei: 55; Percent normal cells: 20; Percent necrosis: 6; Percent stromal cells: 52; Percent lymphocyte infiltration: 36; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
